Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3351, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3351-01A (Primary Tumor).

[page 1 of 2]
PATIENT INFORMATION

D.O.
SSN
MRN
Ref Physician:

PHYSICIAN INFORMATION

SPECIMEN INFORMATION

Collected:
Received:
Reported:

Accession #
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Kidney, right, radical nephrectomy:
Renal cell carcinoma.

Tumor Characteristics:

1. Histologic type: Renal cell carcinoma, clear cell type.
2. Tumor site: Middle and lower poles of right kidney.
3. Tumor size: 8.4 x 7.9 x 3.4 cm.
4. Macroscopic extent of tumor: Tumor is limited to kidney.
5. Nuclear grade: Fuhrman grade: 2 of 4.
6. Lymphovascular space invasion: Absent.
7. Transcapsular invasion: Absent.
8. Renal vein invasion: Absent.
9. Venacaval invasion: Venacava not resected.
10. Adrenal gland: No significant pathology.

Surgical Margin Status:

1. Soft tissue margins: No evidence of malignancy.
2. Ureteral margin: No evidence of malignancy.
3. Vascular Margins: No evidence of malignancy.

Lymph Node Status:

None resected.

Other Significant Findings:

1. The remainder of the kidney demonstrates focal interstitial chronic inflammation.
2. pTNM stage: pT2 NX MX.

Staging Sheet #36.

Electronic Signature:

CLINICAL INFORMATION

[page 2 of 2]
PATIENT INFORMATION

SPECIMEN INFORMATION

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Abdominal mass, unspecific site.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Right kidney (tissue study)

SPECIMEN DATA

GROSS DESCRIPTION:

Received in formalin labeled [REDACTED] and #1 right kidney (tissue study) is a 640 gm previously bisected nephrectomy specimen, consisting of a 13.8 x 8.1 x 3.6 cm kidney, with a moderate amount of attached perinephric fat. There is a minimal amount of attached renal vein and artery, and a 5.5 x 0.2 cm segment of ureter at the hilum. The capsule is smooth and tan-gray. The cut surface consists of an 8.4 x 7.9 x 3.4 cm, mottled tan-red to orange-yellow mass involving the middle and lower poles. The cut surface of the mass consists of cystic, hemorrhagic, red-orange to yellow soft tissue. The mass grossly appears to abut the capsule and is 0.2 cm from the inked deep margin. The mass does not involve the renal vein margin. The remainder of the cut surface consists of red-brown parenchyma. The corticomedullary junction is well-defined. The urothelium is glistening gray-white. The adrenal gland is present. No obvious lymph nodes are identified. The specimen is inked, serially sectioned, and representative sections are submitted as labeled:

Block 1 - ureteral and vascular margins; blocks 2 and 3 - mass to inked deep margin; block 4 - mass to uninvolved parenchyma; block 5 - mass to capsule; blocks 6 to 8 - mass; block 9 - uninvolved parenchyma; block 10 - adrenal gland. The blocks are labeled [REDACTED]. Also received in the same container is a green-yellow and blue cassette labeled [REDACTED] for genomic research study.

*** END OF REPORT ***

Source: NCI Genomic Data Commons file 7cfc1620-3db4-4aa2-bffc-61ced2bc8e77 (TCGA-A3-3351.E020A67D-B3DB-48FD-B0D8-4B25784C390C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).